Somatic mutation profile of tumor specimen TCGA-DV-5567-01A (aliquot TCGA-DV-5567-01A-01D-1534-10) from TCGA case TCGA-DV-5567, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 40.1 years (14,642 days).
Specimen TCGA-DV-5567-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73e6b73f-670d-4086-ba0d-c125e494de79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DV-5567-10A (Blood Derived Normal), aliquot TCGA-DV-5567-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dcf9161-fb1d-4aed-a252-41f5a491815e

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Nonsense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 44/98 reads (45%) | catalogued as rs367545984, CM951297, CM951298, COSV56554814; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C20orf194 | c.2282G>T p.S761I | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99330323; called by muse, mutect2, varscan2
- CACHD1 | c.617G>C p.C206S | Missense Mutation (SNP) | VAF 123/350 reads (35%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.916); catalogued as COSV99261521; called by muse, mutect2, varscan2
- COL4A2 | c.1405G>A p.G469R | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100847252; called by muse, mutect2, varscan2
- COL5A1 | c.2971G>A p.G991S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777368013, COSV100879575; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC10 | c.1413G>A p.W471* | Nonsense Mutation (SNP) | VAF 144/402 reads (36%) | catalogued as COSV99898915; called by muse, mutect2, varscan2
- EIF2B2 | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as CD013636, COSV99837628; called by muse, mutect2, varscan2
- GDI2 | c.647T>C p.L216S | Missense Mutation (SNP) | VAF 96/322 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101200736; called by muse, mutect2, varscan2
- KANSL1L | c.2213G>T p.S738I | Missense Mutation (SNP) | VAF 186/538 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.219); catalogued as COSV55989573, COSV99910199; called by muse, varscan2
- KCNG1 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100856992; called by muse, mutect2, varscan2
- MAP4K5 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 139/437 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs1260633145, COSV50152703, COSV50160172; called by muse, mutect2, varscan2
- MUC20 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs1166036065, COSV100290930; called by muse, mutect2, varscan2
- PWWP2A | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV100193706, COSV61045602; called by muse, mutect2
- CLDN16 | c.627C>T p.A209= | Silent (SNP) | VAF 74/238 reads (31%) | catalogued as rs745542693, COSV99289875; called by muse, mutect2, varscan2
- ZXDA | c.921C>T p.C307= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs778310777, COSV100699368; called by muse, mutect2, varscan2
